Gene-level copy-number profile of tumor specimen TCGA-XQ-A8TA-01A from TCGA case TCGA-XQ-A8TA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.9 years (21,889 days).
Specimen TCGA-XQ-A8TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a3924d65-0b06-45f9-b367-564c3c7e6d6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XQ-A8TA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2c4f8180-bf41-4502-a644-81a9f752b5e6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 15; copy number 2: 12,478; copy number 3: 3,845; copy number 4: 34,955; copy number 5: 2,002; copy number 6: 4,190; copy number 7: 1,912; copy number 8: 7; copy number 9: 7; copy number 12: 19; copy number 13: 2; copy number 14: 105; copy number 15: 10; copy number 16: 26; copy number 17: 98; copy number 18: 42; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XQ-A8TA-01A-11D-A363-01): tumor purity 0.97, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,372,736–51,394,730, 2 genes: AC010478.1, ISL1.
- chr5:59,039,761–59,063,503, 1 gene (within-gene range 0–2): AC092343.1.
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–89,556,641, 38 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1.
- chr10:89,592,747–89,592,827, 1 gene: MIR107.
- chr13:31,199,975–32,788,178, 23 genes (within-gene range 0–2): B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1.
- chr19:42,086,110–42,390,297, 18 genes: POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2, AC006486.3, ZNF526, GSK3A, AC006486.1, AC006486.2, ERF, CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN.
- chr19:42,401,514–42,442,946, 3 genes (within-gene range 0–4): LIPE, AC011497.1, CXCL17.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 318 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:5,126,046–5,490,220, 10 genes, copy number 12: RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1.
- chr5:21,750,673–22,853,344, 7 genes, copy number 9 (within-gene range 7–9): CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1.
- chr9:88,627,063–88,803,716, 3 genes, copy number 15: LINC02843, AL390791.1, MIR4289.
- chr9:89,005,771–89,178,818, 2 genes, copy number 12 (within-gene range 3–12): SHC3, AL353150.1.
- chr9:89,360,787–89,498,130, 3 genes, copy number 14 (within-gene range 2–14): SEMA4D, PA2G4P6, AL590233.1.
- chr9:90,020,654–90,041,499, 2 genes, copy number 13 (within-gene range 4–13): MIR4290HG, MIR4290.
- chr9:91,563,091–91,950,228, 1 gene, copy number 15 (within-gene range 6–15): ROR2.
- chr9:93,318,199–93,566,112, 6 genes, copy number 17: C9orf129, RNU6-829P, Y_RNA, AL583839.1, FAM120AOS, FAM120A.
- chr9:94,318,196–94,512,879, 9 genes, copy number 16: NUTM2F, AL691447.2, AL691447.1, PTMAP12, MFSD14B, YRDCP1, AL358232.2, AL358232.1, RNU6-669P.
- chr9:95,099,054–95,426,796, 1 gene, copy number 17 (within-gene range 4–17): FANCC.
- chr9:95,292,338–95,876,049, 13 genes, copy number 17: AL157384.1, AL161729.3, MT1P1, PTCH1, AL161729.2, AL161729.1, AL161729.4, AL392185.1, AL354861.2, AL354861.1, LINC00476, AL354861.3, RNU2-46P.
- chr9:95,905,005–95,918,704, 2 genes, copy number 17: RNA5SP289, AL161454.1.
- chr9:101,028,727–101,410,660, 10 genes, copy number 22 (within-gene range 4–22): PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189.
- chr9:101,449,801–101,563,344, 5 genes, copy number 17: AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20.
- chr9:101,591,604–101,595,021, 1 gene, copy number 17: PPP3R2.
- chr9:102,922,574–105,851,425, 42 genes, copy number 17: AL365396.1, CYLC2, AL589823.1, LINC01492, AL390962.1, RNA5SP291, AL590381.1, SMC2-AS1, SMC2, TOPORSLP, AL512646.1, OR13F1, AL450426.1, OR13C4, OR13C3, OR13C8, OR13D2P, OR13C5, OR13C2, OR13C9, OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5.
- chr9:106,679,977–107,171,148, 10 genes, copy number 17: RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1.
- chr9:107,797,744–108,097,851, 8 genes, copy number 17: RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2.
- chr9:112,040,783–112,890,876, 19 genes, copy number 18 (within-gene range 6–18): SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1, INIP, AL390067.1, SNX30, SLC46A2, AL139041.1.
- chr9:113,349,541–113,597,743, 7 genes, copy number 12: BSPRY, HDHD3, ALAD, POLE3, C9orf43, RGS3, AL162727.2.
- chr9:114,323,056–114,505,473, 5 genes, copy number 14 (within-gene range 4–14): ORM1, ORM2, AKNA, AL138895.1, WHRN.
- chr9:115,252,538–115,254,251, 1 gene, copy number 17: AL355601.1.
- chr9:121,074,753–121,463,370, 9 genes, copy number 17 (within-gene range 6–17): CNTRL, RAB14, RN7SL181P, GSN, AL513122.1, AL513122.2, GSN-AS1, STOM, AL359644.1.
- chr9:122,661,566–123,115,477, 22 genes, copy number 18: OR1L1, OR1L3, TLK1P1, OR1L4, OR1L6, SKA2P1, OR5C1, PDCL, OR1K1, KRT18P67, RC3H2, SNORD90, ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG.
- chr9:123,111,546–123,111,643, 1 gene, copy number 18: MIR600.
- chr9:124,862,130–125,143,528, 5 genes, copy number 15 (within-gene range 6–15): ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2.
- chr9:126,860,665–128,542,288, 70 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr9:133,061,978–133,479,127, 27 genes, copy number 14: CEL, CELP, RALGDS, AL162417.1, GBGT1, OBP2B, LCN1P1, ABO, Y_RNA, LCN1P2, SURF6, Y_RNA, MED22, AL772161.1, RPL7A, SNORD24, SNORD36B, SNORD36A, SNORD36C, SURF1, SURF2, SURF4, STKLD1, REXO4, ADAMTS13, CACFD1, SLC2A6.
- chr9:134,527,182–134,995,854, 17 genes, copy number 16 (within-gene range 4–16): AL669970.3, AL669970.2, COL5A1, COL5A1-AS1, AL645768.1, MIR3689C, MIR3689A, MIR3689D1, MIR3689B, MIR3689D2, MIR3689E, MIR3689F, AL603650.1, FCN2, FCN1, AL353611.1, AL353611.2.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
